Somatic mutation profile of tumor specimen TCGA-QR-A7IP-01A (aliquot TCGA-QR-A7IP-01A-11D-A35D-08) from TCGA case TCGA-QR-A7IP, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Extra-adrenal paraganglioma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 30.3 years (11,051 days).
Specimen TCGA-QR-A7IP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 289d9662-196f-4226-8b5d-cda5c2407f4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A7IP-10A (Blood Derived Normal), aliquot TCGA-QR-A7IP-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68899aa2-7bb1-4d44-9ea6-c9fd029ba5a2

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTL8 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs267598220, COSV64861450; called by muse, mutect2, varscan2
- IGSF22 | c.2215C>T p.R739* (on ENST00000319338; = p.R840* on NM_173588.4) | Nonsense Mutation (SNP) | VAF 33/48 reads (69%) | catalogued as rs531575688, COSV60038196; called by muse, mutect2, varscan2
- LUM | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57128428; called by muse, mutect2, varscan2
- STX8 | c.682G>A p.V228M | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as rs904892581; called by muse, mutect2, varscan2
- TTLL1 | c.274G>A p.G92R | Missense Mutation (SNP) | VAF 49/268 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.127); catalogued as rs1281794480; called by muse, mutect2, varscan2
- PSG2 | c.347A>G p.D116G | Missense Mutation (SNP) | VAF 218/555 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- TACC2 | c.1725C>A p.S575R | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.047); called by muse, mutect2, varscan2
